Somatic mutation profile of tumor specimen C3N-00302-02 (aliquot CPT0008750012) from CPTAC case C3N-00302, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 59.0 years (21,532 days).
Specimen C3N-00302-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ccf9146f-3d85-4568-9fe7-64ab9aa59bae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00302-31 (Blood Derived Normal), aliquot CPT0008790002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1baf8a1-96af-453f-a48f-99faea75510f

The open-access MAF lists 34 somatic variants for this specimen: 18 protein-altering or splice-affecting, 10 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 10, Frame Shift Del 4, Intron 3, 3'UTR 1, 5'UTR 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 82/344 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1018del p.M340Cfs*5 | Frame Shift Del (DEL) | VAF 74/251 reads (29%) | catalogued as rs1131691005, COSV53461649, COSV53588660; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- APOB | c.4796G>A p.R1599H | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.193); catalogued as rs746414462, COSV51927055; ClinVar: likely benign; called by muse, mutect2
- COPG1 | c.418A>G p.I140V | Missense Mutation (SNP) | VAF 43/216 reads (20%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.768); catalogued as rs367768969; called by muse, mutect2, varscan2
- IL20RB | c.442G>C p.D148H | Missense Mutation (SNP) | VAF 24/313 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.085); catalogued as COSV100290891, COSV100291102; called by muse, mutect2
- IRS1 | c.2771C>T p.P924L | Missense Mutation (SNP) | VAF 127/560 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs747061950; called by muse, mutect2, varscan2
- KRTAP4-8 | c.68C>A p.T23N | Missense Mutation (SNP) | VAF 56/204 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.089); catalogued as rs753185136; called by muse, mutect2, varscan2
- LTBP2 | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 44/328 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753186679; called by muse, mutect2, varscan2
- LVRN | c.2756+2T>A p.X919_splice | Splice Site (SNP) | VAF 16/113 reads (14%) | catalogued as COSV100773325; called by muse, varscan2
- OR5R1 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs771782696, COSV56571910; called by muse, mutect2
- OSR1 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 68/320 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.818); catalogued as rs1236849681; called by muse, mutect2, varscan2
- PCDHB5 | c.2266G>A p.G756R | Missense Mutation (SNP) | VAF 71/250 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.127); catalogued as rs781995647, COSV50647659; called by muse, mutect2, varscan2
- PCDHGB3 | c.1865G>A p.R622H | Missense Mutation (SNP) | VAF 34/231 reads (15%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.819); catalogued as rs1229622208; called by muse, mutect2, varscan2
- TBX20 | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as rs1363662149; called by muse, mutect2
- MIDEAS | c.3007G>A p.E1003K | Missense Mutation (SNP) | VAF 106/479 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- RB1 | c.1749del p.D584Ifs*27 | Frame Shift Del (DEL) | VAF 119/330 reads (36%) | called by mutect2, pindel, varscan2
- SCRN1 | c.887_893del p.G296Vfs*17 | Frame Shift Del (DEL) | VAF 18/76 reads (24%) | called by mutect2, pindel
- ZNF407 | c.691del p.H231Ifs*29 | Frame Shift Del (DEL) | VAF 47/199 reads (24%) | called by mutect2, pindel, varscan2
- CLIP3 | c.300C>T p.G100= | Silent (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- CORO2B | c.252C>T p.C84= | Silent (SNP) | VAF 80/230 reads (35%) | catalogued as rs775653466, COSV99962893; called by muse, mutect2, varscan2
- HAO2 | c.1029A>T p.R343= | Silent (SNP) | VAF 50/241 reads (21%) | called by muse, mutect2, varscan2
- LAMC2 | c.1353C>T p.N451= | Silent (SNP) | VAF 66/421 reads (16%) | catalogued as rs141522697; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYF6 | c.264A>G p.K88= | Silent (SNP) | VAF 131/578 reads (23%) | called by muse, mutect2, varscan2
- PATL2 | c.990C>T p.C330= | Silent (SNP) | VAF 44/159 reads (28%) | called by muse, mutect2, varscan2
- SATB1 | c.942T>A p.P314= | Silent (SNP) | VAF 51/245 reads (21%) | called by muse, mutect2, varscan2
- TMEM259 | c.180C>T p.F60= | Silent (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2, varscan2
- UBA3 | c.87G>T p.G29= | Silent (SNP) | VAF 48/191 reads (25%) | called by muse, mutect2, varscan2
- ZNF865 | c.558G>A p.P186= | Silent (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- AK2 | c.*609G>C | 3'UTR (SNP) | VAF 26/292 reads (9%) | called by muse, mutect2
- COL1A2 | c.2349+24G>A | Intron (SNP) | VAF 49/396 reads (12%) | catalogued as rs762824227; called by muse, mutect2, varscan2
- CRB2 | c.3389+22G>A | Intron (SNP) | VAF 30/139 reads (22%) | catalogued as rs943584708; called by muse, mutect2, varscan2
- RAC1 | c.226-1414G>A | Intron (SNP) | VAF 35/198 reads (18%) | catalogued as rs148122613; called by muse, mutect2, varscan2
- REL | c.-93G>T | 5'UTR (SNP) | VAF 29/87 reads (33%) | called by muse, mutect2, varscan2
- SPATA31C2 | n.2689G>A | RNA (SNP) | VAF 54/338 reads (16%) | catalogued as rs760047563; called by muse, mutect2, varscan2
